Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A29L, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A29L-06A (Metastatic).

[page 1 of 2]
DCB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma to right axilla. Fresh for tumour bank + histo. Excision biopsy lesion -> suture proximal ring finger right hand. Excision biopsy lesion right temple.

MACROSCOPIC DESCRIPTION

(Dr

Three specimens were received.

1. "RIGHT AXILLARY CONTENTS". Specimen received fresh and two thirds of largest tumour nodule (35mm across), taken for Melanoma Tumour Banking. An irregular piece of fibrofatty tissue 190 x 110 x 70mm including skeletal muscle up to 70mm across. No orientating sutures are identified. Multiple lymph nodes were identified, including enlarged involved lymph nodes up to 35mm across. Other small lymph nodes were identified measuring up to 7mm across. Cut section of the skeletal muscle shows no unusual features.

- A. 1 node bisected.
- B. 1 involved node bisected.
- C. 5 nodes.
- D. Full face of involved node.
- E. Full face of largest involved node.
- F. Full face of involved node.
- G. Full face of partially involved node.
- H. 3 nodes.
- I. 1 node bisected.
- K. Involved lymph node bisected.
- L. Full face of involved node.
- M. 1 node bisected.

All of lymph nodes embedded sequentially from one end to opposite end.

2. "LESION RIGHT RING (FOURTH) FINGER STITCH PROXIMAL". An ellipse of skin 20 x 16 x 4mm with an ulcerated plaque centrally 16 x 9mm. A suture marks one long margin (proximal), designated 12 o'clock. 12 o'clock inked blue, 6 o'clock black. Five transverse sections through almost all of lesion embedded from 3 to 9 o'clock showing 12 and 6 o'clock margins

- A. Two sections.
- B. Three sections.
- C. Two longitudinal sections 3 o'clock.
- D. Two longitudinal sections, 9 o'clock.
- Please refer to diagram.

3. "LESION RIGHT TEMPLE". An ellipse of skin 23 x 13mm with subcutis to a depth of 4mm. On the surface is a light grey and cream irregular plaque 9 x 9mm, lying just clear of the margins. A possible suture is present at one pole (designated 12 o'clock). 3 o'clock inked blue, 9 o'clock black. Tips trimmed, four transverse sections through all of lesion embedded sequentially from 12 to 6 o'clock and showing 3 and 9 o'clock margins.

ICD-O-3
Melanoma, NOS 8720/3
Site: lymph node, Axilla C77.3
hw 6/2/11

hw 6/2/11		

A Unit of

Printed:

This fax was received by (

[page 2 of 2]
Requested by

MRN/NI:

Location:

Accession:

HISTOPATHOLOGY REPORT

A. Two sections.

B. Two sections.

MICROSCOPIC REPORT

1. "RIGHT AXILLARY CONTENTS". The sections show 16 lymph nodes and adjacent adipose tissue. Twelve of the lymph nodes are variably replaced by a pleomorphic, mostly spindle cell tumour with focal epithelioid areas consistent with metastatic melanoma. There are focal large areas of necrosis. Two of the nodes (B & K) show focal extranodal spread (1.9 x 0.6mm and 1.0 x 0.2mm respectively). Immunostains for S100 and HMB45 performed on block 1F show that the tumour cells are positive for both of these markers consistent with melanoma.

2. "LESION RIGHT RING (FOURTH) FINGER STITCH PROXIMAL ". The sections show skin and underlying subcutis with a superficially ulcerated infiltrating carcinoma. It shows focal keratinisation and intercellular bridge formation consistent with a moderately differentiated squamous cell carcinoma. It extends into the dermis 1.9mm beneath the surface. The tumour extends to within less than 0.1mm to virtually about the 9 o'clock margin (block D). It is 0.6mm clear of the black inked 6 o'clock margin, 1.2mm clear of the deep margin and 1.9mm clear of the blue inked 12 o'clock margin. No lymphovascular or perineural invasion by tumour is seen. Fibrosis consistent with dermal scarring is present deep to the tumour. Clinicopathological correlation is suggested.

3. "LESION RIGHT TEMPLE". The sections show skin with a nodular basal cell carcinoma. It shows focal cystic change and extends to 2.5mm beneath the skin surface. It is 0.7mm clear of the nearest peripheral margin (black ink 9 o'clock margin) and is 1.5mm clear of the deep margin.

SUMMARY

1. Right axillary contents : **METASTATIC MELANOMA IN 12 OF 16 LYMPH NODES**, Please see report.

2. Skin of right ring finger : **SQUAMOUS CELL CARCINOMA**, Please see report.

3. Skin of right temple : **BASAL CELL CARCINOMA**, Please see report.

REPORTED BY Prof

A Unit of

Printed:

Page 2 of 2

This fax was received by (

Source: NCI Genomic Data Commons file 87f4e9f3-467b-4c88-a581-0cd95e88b76a (TCGA-EE-A29L.99F4D416-52E2-4225-9682-28802B61F9AC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).